Somatic mutation profile of tumor specimen TCGA-98-A53H-01A (aliquot TCGA-98-A53H-01A-12D-A25L-08) from TCGA case TCGA-98-A53H, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.5 years (27,928 days).
Specimen TCGA-98-A53H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 187b4fa8-9403-4ac3-9a93-fabacac24ddd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-A53H-10A (Blood Derived Normal), aliquot TCGA-98-A53H-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca2412c8-f0db-4b88-a7c5-54d4c0bfabf8

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB7 | c.1548G>T p.R516S (on ENST00000373394 / NM_001271696.3; = p.R517S on NM_004299.6) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99504570; called by muse, mutect2
- AIFM1 | c.859-1G>T p.X287_splice | Splice Site (SNP) | VAF 9/101 reads (9%) | catalogued as COSV99781050, COSV99781190; called by muse, mutect2
- ATP2A3 | c.2401G>T p.G801C | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99989411; called by muse, mutect2
- CNTNAP2 | c.3356G>T p.R1119L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM080156, COSV100668360, COSV62191661; called by muse, mutect2
- FATE1 | c.435C>A p.N145K | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV64848895; called by muse, mutect2
- L1CAM | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100649338; called by muse, mutect2
- MAGEA10 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV99726803; called by muse, mutect2
- MAGEA4 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV99367610; called by muse, mutect2
- MMP16 | c.1286C>G p.T429S | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54166421, COSV99689340; called by muse, mutect2
- NONO | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99338982; called by muse, mutect2
- PIP4K2C | c.488A>T p.H163L | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100723982; called by muse, mutect2
- RTL9 | c.3358A>G p.T1120A | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); catalogued as COSV101511742; called by muse, mutect2
- RYR2 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100771862; called by muse, mutect2
- TRPC5 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV99461795; called by muse, mutect2
- UCK2 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903016; called by muse, mutect2
- UNC13A | c.1457T>C p.I486T | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99408913; called by muse, mutect2
- UBE2NL | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- OBSCN | c.11226G>T p.P3742= | Silent (SNP) | VAF 16/240 reads (7%) | catalogued as COSV52791382; called by muse, mutect2
- ST18 | c.735T>C p.P245= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV99390319; called by muse, mutect2
